Somatic mutation profile of tumor specimen MBCProject_0003_T2_WES (aliquot MBCProject_0003_T2_WES_1) from CMI case MBCProject_0003, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.6 years (15,931 days).
Specimen MBCProject_0003_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7345c3cb-2755-42d1-9a27-be6859930e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0003_SALIVA (Saliva), aliquot MBCProject_0003_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42b842e3-8105-477c-8dd4-b38ee3282cab

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 8, Intron 7, Nonsense Mutation 5, In Frame Del 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ASB11 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs761707523, COSV60355973; called by muse, varscan2
- CCDC188 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1223308379; called by muse, mutect2
- CFHR4 | c.216C>G p.C72W (on ENST00000367416 / NM_001201551.2; = p.C73W on NM_006684.5) | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV52228741; called by muse, mutect2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- DZANK1 | c.1981G>A p.V661M (on ENST00000262547 / NM_001099407.1; = p.V468M on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs766364620, COSV52757136; called by muse, mutect2, varscan2
- EXOC6B | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55560705; called by muse, mutect2, varscan2
- FCRL2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1395454743, COSV63834194; called by muse, mutect2, varscan2
- FFAR3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 240/2290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765904411; called by muse, mutect2, varscan2
- FMN2 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); catalogued as rs142072223, COSV60444287; called by muse, varscan2
- GPC3 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1569458691; ClinVar: uncertain significance; called by muse, varscan2
- KIF26B | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 146/568 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750881727; called by muse, mutect2, varscan2
- LCE5A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 103/492 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.485); catalogued as rs1423735491, COSV57500082; called by muse, mutect2, varscan2
- MRGPRG | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1160877464; called by muse, mutect2, varscan2
- MYO3B | c.2686G>C p.A896P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.555); catalogued as rs753999476, COSV58698249; called by muse, mutect2, varscan2
- PLCB1 | c.2891C>A p.A964D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100569348; called by muse, mutect2, varscan2
- PRDM13 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); catalogued as rs1421239685; called by muse, mutect2, varscan2
- PTEN | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV64310770; called by muse, mutect2, varscan2
- SEMA5A | c.3079A>T p.K1027* | Nonsense Mutation (SNP) | VAF 48/355 reads (14%) | catalogued as COSV66801833; called by muse, mutect2
- SLC26A11 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.033); catalogued as COSV63280020; called by muse, mutect2, varscan2
- SLC6A11 | c.1575G>A p.A525= | Splice Region (SNP) | VAF 21/153 reads (14%) | catalogued as rs1320790036, COSV99594405; called by muse, mutect2, varscan2
- TRAF3 | c.1234G>T p.A412S | Missense Mutation (SNP) | VAF 45/516 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV100693598; called by muse, mutect2
- ALPP | c.871T>G p.F291V | Missense Mutation (SNP) | VAF 92/1375 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COBLL1 | c.2845A>C p.K949Q (on ENST00000392717; = p.K911Q on NM_014900.5) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CPEB1 | c.40_57del p.I14_H19del | In Frame Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- ERMARD | c.1854-4_1854delinsTTTTT p.X618_splice | Splice Site (ONP) | VAF 6/62 reads (10%) | called by mutect2*, pindel
- FRMPD4 | c.1054T>A p.S352T | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- GRM4 | c.1877G>C p.S626T | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HAPLN2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- KIF24 | c.3346T>A p.S1116T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2
- KIF2A | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.093); called by muse, mutect2
- KMT2C | c.8950del p.S2984Lfs*6 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel
- OR4X2 | c.372C>G p.Y124* | Nonsense Mutation (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.2254G>T p.V752F | Missense Mutation (SNP) | VAF 52/521 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- PDZD2 | c.3262G>T p.E1088* | Nonsense Mutation (SNP) | VAF 52/399 reads (13%) | called by muse, mutect2, varscan2
- PLXDC1 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PPFIA4 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 78/637 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- RAX | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 83/515 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RHPN2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 25/442 reads (6%) | called by muse, mutect2
- SLC6A17 | c.2107C>A p.L703M | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPTB | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 41/293 reads (14%) | called by muse, mutect2, varscan2
- TMEM176A | c.286-2A>G p.X96_splice | Splice Site (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2
- TXNDC2 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZFYVE28 | c.2435dup p.E813Gfs*130 | Frame Shift Ins (INS) | VAF 36/300 reads (12%) | called by mutect2, pindel, varscan2
- ZNF804A | c.458_460del p.Q153del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- ARRDC3 | c.828T>G p.S276= | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, varscan2
- CDC42EP2 | c.522G>A p.L174= | Silent (SNP) | VAF 78/552 reads (14%) | catalogued as rs1287865914; called by muse, mutect2, varscan2
- FAT1 | c.352T>C p.L118= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- PCDHB7 | c.1677C>G p.P559= | Silent (SNP) | VAF 193/1650 reads (12%) | called by muse, mutect2, varscan2
- PTPN7 | c.375C>T p.Y125= (on ENST00000495688; = p.Y164= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 95/309 reads (31%) | catalogued as rs746969309; called by muse, mutect2, varscan2
- SALL3 | c.429C>T p.R143= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1467425547, COSV73306407; called by muse, mutect2
- SYT11 | c.843C>T p.I281= | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2
- ZMAT3 | c.579A>G p.Q193= | Silent (SNP) | VAF 20/206 reads (10%) | catalogued as rs749452113; called by muse, varscan2
- CLDN15 | c.217+565C>T | Intron (SNP) | VAF 51/541 reads (9%) | catalogued as rs1299213567; called by muse, mutect2
- DST | c.4296+4618del | Intron (DEL) | VAF 27/238 reads (11%) | called by mutect2, pindel, varscan2
- EXD1 | c.28+3963C>G | Intron (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- FCRL2 | c.1279+38G>C | Intron (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- ICA1 | c.804+127C>T | Intron (SNP) | VAF 7/82 reads (9%) | catalogued as rs1241481524; called by muse, mutect2
- INTS11 | c.126+175G>T | Intron (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156188 G>A | 3'Flank (SNP) | VAF 31/266 reads (12%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7308C>G | Intron (SNP) | VAF 15/147 reads (10%) | called by muse, mutect2, varscan2
- TMC1 | c.*43G>C | 3'UTR (SNP) | VAF 18/117 reads (15%) | catalogued as rs756617297; called by muse, mutect2, varscan2
